Somatic mutation profile of tumor specimen 0DP7LM from CCDI case PBCDIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.9 years (3,995 days).
Specimen 0DP7LM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89018a02-5398-46b5-a57c-1762a1958b76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP7LB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1cee8d3-61b5-4cb6-b19f-d25cfe0e9b80

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FXYD5 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 181/496 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs755229821; called by muse, mutect2, varscan2
- IL13RA1 | c.556T>A p.S186T | Missense Mutation (SNP) | VAF 313/778 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TNRC18 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
